Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A2PT, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A2PT-01A (Primary Tumor).

[page 1 of 3]
Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type: INPATIENT
Additional Copy to:

Clinical Diagnosis & History:
Thyroid papillary carcinoma on FNA right lobe.

Specimens Submitted:

- 1: Right paratracheal nodes (fs)
- 2: Total thyroid
- 3: Pretracheal tissue
- 4: Right mediastinal tissue
- 5: Left mediastinal tissue

DIAGNOSIS:

1. Right paratracheal nodes (fs):

Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 5

2. Total thyroid:

Tumor Type:
Papillary carcinoma, tall cell variant

Mitotic Activity:
Not identified

Tumor Necrosis:
Not identified

Tumor Location:
Right lobe

Tumor Size:
Greatest diameter is 1.5 cm.

Tumor Encapsulation:
None Identified

Blood Vessel Invasion:
Focal Invasion

Extrathyroid Extension:
Invades: perithyroidal fibroadipose tissue and skeletal muscle

Surgical Margins:
Free of tumor

Tumor Multicentricity:
Not identified

ICD-O-3
carcinoma, papillary, tall cell variant
8344/3
site: thyroid, NOS C73.9
/w 8/31/11

[page 2 of 3]
Adenoma(s) (away from the carcinoma):

Not identified

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

Exhibits chronic lymphocytic thyroiditis

Parathyroid Glands:

Not identified

Lymph Nodes:

Three lymph nodes negative for metastatic carcinoma are identified (0/3)

3. Pretracheal tissue:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 6

4. Right mediastinal tissue:

Lymph Node Dissection:

Benign fibroadipose tissue

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

2. The specimen is received fresh labelled "total thyroid, stitch marks right thyroid lobe" and consists of a thyroid weighing 12.5 g. The right lobe measures 3.5x2x1.5 Cm , the left lobe measures 4x3x1 cm and the isthmus measures 1.2x1x0.6 Cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals overall multinodular thyroid tissue with one prominent nodule with white tan cut surface on the right lobe measuring 1.5x1.2x1.0 cm. Sections through the remaining tissue reveal beefy red parenchyma. The remaining thyroid parenchyma is red tan and beefy. Representative sections of the specimen are submitted for TPS. The remaining tissue is serially sectioned and representatively submitted.

Summary of sections:

N - nodule

RL - right lobe

LL - left lobe

IS - isthmus

3) The specimen is received in formalin labeled, "pretracheal tissue", and consists of multiple pieces of red and tan soft tissue measuring 0.9 x 0.6 x 0.2 cm in aggregate. Entirely submitted.

Summary of sections:

U-- undesignated

[page 3 of 3]
4) The specimen is received in formalin, labeled "right superior mediastinal tissue", and consists of two irregular fragments of pink-tan soft tissue measuring 0.4 and 1.8 cm in greatest dimension. Submitted entirely.

Summary of sections:
U -- undesignated

5) The specimen is received in formalin, labeled "left superior mediastinal tissue", and consists of an irregular fragment of pink-tan soft tissue measuring 0.5 cm in greatest dimension. Entirely submitted.

Summary of sections:
U- undesignated

Summary of Sections:

Part 1: Right paratracheal nodes (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 2: Total thyroid

Block	Sect. Site	PCs
1	IS	1
2	LL	2
4	N	4
3	RL	3

Part 3: Pretracheal tissue

Block	Sect. Site	PCs
1	U	4

Part 4: Right mediastinal tissue

Block	Sect. Site	PCs
1	U	2

Part 5: Left mediastinal tissue

Block	Sect. Site	PCs
1	U	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen section diagnosis: Right paratracheal nodes (fs): Benign
Permanent diagnosis: same

Source: NCI Genomic Data Commons file 0de51838-5eec-4dd3-8bb7-bf6e4d7e62ab (TCGA-DJ-A2PT.0C47594E-54FF-4DC6-BB4C-FC0861570B22.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).